FM case AD16077 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/557d9c39-9474-4b21-aad6-f26bbd525e3f

Male, 64.9 years: Merkel cell carcinoma (ICD-O-3 8247/3) of the skin; metastasis biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
